Surgical pathology report (de-identified scan), TCGA case TCGA-14-3476, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-3476-01B (Primary Tumor).

[page 1 of 4]
Document Type: AP Report
Document Date: [REDACTED]
Document Status: Modified
Document Title: AP REPORT

*** Final Report ***

SUPPLEMENTAL REPORT

SUPPLEMENTAL DIAGNOSIS:

Previous diagnosis remains unchanged. See. Molecular Diagnostics
Reprot
results for Block 1A.

COMMENT:

This test was not requested, performed or reported at [REDACTED]

[REDACTED] Department of Pathology.

The test was requested by [REDACTED]. The test was performed and
results
reported by Center for [REDACTED].

Results are included with this Surgical Pathology report so that
all available
information on this tumor may be accessed at one site.

MGMT GENE AMPLIFICATION

DNA was isolated from a paraffin embedded block of the brain tumor
biopsy [REDACTED].

DNA methylation patterns in the CpG island of the
MGMT gene [REDACTED]

[REDACTED] was determined
by chemical

(bisulfite) modification of unmethylated, but not methylated,
cytosines to

uracil and subsequent PCR using primers specific for either
methylated or the

modified unmethylated DNA [REDACTED]

The

PCR products were analyzed in duplicate parallel runs by capillary
gel

electrophoresis. The sensitivity of the assay based on DNA

[page 2 of 4]
[REDACTED]

dilution studies
is at least 1:1000.

RESULT:

The analyzed region of the MGMT promoter is UNMETHYLATED.

INTERPRETATION:

MGMT (O6 methylguanine DNA methyltransferase) is a DNA repair gene. Methylation of the promoter leads to gene silencing and loss of MGMT expression. a recent study that tested the methylation status of the same region of the MGMT promoter in glioblastomas found that MGMT promoter methylation was an independent favorable prognostic factor and was associated with a survival benefit in patients treated with temozolamide and radiotherapy.

[REDACTED] and Benefit from
Temozolomide
in Glioblastomas. [REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. RIGHT FRONTAL BRAIN LESION, RESECTION, FS1A, TP1A:
- GLIOBLASTOMA WITH OLIGODENDROGLIOMA COMPONENT, WHO GRADE IV.
- SEE COMMENT.
2. RIGHT FRONTAL BRAIN LESION, RESECTION:
- GLIOBLASTOMA WITH OLIGODENDROGLIOMA COMPONENT, WHO GRADE IV.
- SEE COMMENT.
- [REDACTED]

SURGICAL PATHOLOGY REPORT

COMMENT:

This glioblastoma has an element of oligodendroglioma within it, comprising approximately 20% of neoplastic cells. Perhaps more morphologically impressive is the high degree of angiogenesis and the extensive reactive stromal component associated with it. In the majority of this reaction, the matrix has a myxoid appearance whereas in others of the stroma has a more highly spindled and collagen-rich. These stromal

[page 3 of 4]
elements are

interpreted as a reactive process associated with the angiogenesis because of

the geographic association of these two processes. FISH analysis of EGFR and

1p/19q have been ordered and the results will be issued in a separate

report. Tissue has been sent for MGMT analysis and the results will be issued

in a separate report.

SPECIMEN:

1. Right frontal brain lesion.
2. Right frontal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Right craniotomy. Brain tumor.

GROSS DESCRIPTION:

Two specimens are received, each labeled with the patient's name and medical record number.

Specimen #1 is received fresh for intraoperative consultation and is labeled

as "right frontal brain lesion." The specimen consists of multiple fragments

of pink-tan, soft tissue measuring in aggregate, 0.8 x 0.8 x 0.6 cm.

Representative sections are submitted for frozen section diagnosis and the

contents of the cryoblock are transferred to cassette "FS1A." A touch prep is

also performed. The remainder of the specimen is submitted in cassette

"1B."

Specimen #2 is received in formalin and is labeled as "right frontal brain

lesion." It consists of multiple fragments of brain with adherent hemorrhage

measuring 4.0 x 3.8 x 2.3 cm in aggregate. The entire specimen is submitted

in cassettes "2A" through "2G." Dictated by

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: RIGHT FRONTAL BRAIN LESION, BIOPSY (FROZEN SECTION, TOUCH

PREPARATION): GLIOBLASTOMA.

Frozen Section results were communicated to the surgical team and

were repeated back by

[page 4 of 4]
Pathologist: [REDACTED]

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

SPECIAL STAINS:

FISH	DONE
FISH	DONE
FISH	DONE
FISH	DONE
FISH	DONE
FISH	DONE

FLUORESCENCE IN SITU HYBRIDIZATION

SPECIMEN:

Brain, right frontal lesion.

CLINICAL HISTORY/REFERRING DIAGNOSIS:

Glioblastoma with oligodendroglioma component, WHO grade IV.

GROSS DESCRIPTION:

Paraffin block 1B.

TEST PERFORMED/PROBES USED:

EGFR gene locus specific probe(7p12)
Chromosome 7 alpha satellite DNA specific probe(7p11.1-7q11.1)

Probe for chromosome 1p36
Probe for chromosome 1q25

Probe for chromosome 19p13
Probe for chromosome 19q13

RESULTS:

NEGATIVE for EGFR gene amplification
nuc ish 7cen(D7Z1x2-10), 7p12(EGFRx2-10) [200/200]

NEGATIVE for chromosome 1p36 deletion
nuc ish(TP73 x 2), (ANGPTL x 2) [170/200]

NEGATIVE for chromosome 19q13 deletion
nuc ish(ZNF443 x 2), (GLTSCR x 2) [166/200]

INTERPRETATION:

Flourescence in situ hybridization was performed using the above listed DNA probes [REDACTED]. The probes were simultaneously hybridized to a section of the formalin-fixed paraffin-embedded tissue submitted for evaluation.

Source: NCI Genomic Data Commons file a625dfcb-6c61-41d2-a7bd-7e0a001d39a4 (TCGA-14-3476.04FF03B7-631F-4C5F-8CDF-874817F2AFE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).